Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5303, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5303-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Brain tumor.

Gross Examination:

A. "Brain tumor (AF1)", received fresh for frozen section. A 2.5 x 2 x up to 0.7 cm aggregate one large and several smaller soft tan tissue is received. A portion as previously been submitted as frozen section AF1. The frozen section remnant is submitted in A1. Representative nonfrozen tissue is retained in formalin and the remainder submitted in A2.

B. "Brain tumor", received fresh and placed in formalin. A 4 x 4 x 1.5 cm aggregate of multiple fragments of soft pink and tan tissue is received. Representative retained in formalin and the remainder sectioned and submitted in B1-B4.

Intraoperative Consultation:

A. "Brain tumor" AF1 - glioma, probable low grade

Microscopic Examination:

The specimen is brain which exhibits a neoplastic proliferation of malignant astrocytic cells. The tumor cells largely exhibit elongated hyperchromatic nuclei. Focally the tumor is moderately hypercellular and formed by numerous gemistocytic forms. Mitotic activity is evident. Vascular proliferation is not seen. There is no evidence of necrosis.

DIAGNOSIS:

A. "BRAIN TUMOR"

ANAPLASTIC ASTROCYTOMA (WHO III);

B. "BRAIN TUMOR"

ANAPLASTIC ASTROCYTOMA (WHO III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Continued on next page...

Page: 1

DATE:

TIME: t

Patient:

MRN:

Location: s

[page 2 of 2]
** END OF REPORT **

Page: 2

DATE:

TIME:

Patient:

HX No:

Location:

Source: NCI Genomic Data Commons file ed35c6a5-8198-4df7-92f9-b408764a4ea3 (TCGA-E1-5303.20E5B4F2-6555-4BF9-80C3-9B472FE8EEDB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).